FM case AD2211 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Small intestine.
https://portal.gdc.cancer.gov/cases/c4a5abb7-ebf7-4c56-a25b-9c2490610152

Male, 70.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the duodenum; primary biopsied or resected from the duodenum. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
